Somatic mutation profile of tumor specimen TCGA-VS-A8EI-01A (aliquot TCGA-VS-A8EI-01A-11D-A37N-09) from TCGA case TCGA-VS-A8EI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 38.7 years (14,129 days).
Specimen TCGA-VS-A8EI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f51e345-1a00-4d91-81c7-232ea0be0c82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A8EI-10A (Blood Derived Normal), aliquot TCGA-VS-A8EI-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/089bd03b-d6f2-47bd-8ff0-15b2f3a7852e

The open-access MAF lists 137 somatic variants for this specimen: 106 protein-altering or splice-affecting, 30 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 30, Nonsense Mutation 11, Splice Site 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN9A | c.2724G>A p.W908* (on ENST00000303354; = p.W897* on NM_002977.3) | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | catalogued as rs121908909, CM066223, COSV100313786; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.2705C>T p.S902L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV99229416; called by muse, mutect2, varscan2
- ABCC9 | c.4058C>T p.S1353L | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs865858522; called by muse, mutect2
- ADAM20 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.326); catalogued as rs764972924, COSV99833548; called by muse, mutect2, varscan2
- ADAMTS8 | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273097024, COSV99961404; called by muse, mutect2, varscan2
- ADGRD1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs144030317; called by mutect2, varscan2
- AK8 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as rs375128507; called by muse, mutect2, varscan2
- ANKRD26 | c.1170G>C p.L390F | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as COSV101066613, COSV101066655; called by muse, mutect2
- ARHGAP45 | c.650+1G>A p.X217_splice | Splice Site (SNP) | VAF 19/52 reads (37%) | catalogued as rs1206577945, COSV100491012; called by muse, mutect2, varscan2
- ARID2 | c.319G>T p.G107W | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100536762; called by muse, mutect2, varscan2
- ATP10A | c.1401G>T p.E467D | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.147); catalogued as COSV100791433; called by muse, mutect2
- BPHL | c.414G>C p.W138C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100984539; called by muse, mutect2, varscan2
- C12orf4 | c.413C>G p.S138C | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV99712880; called by muse, mutect2, varscan2
- CAPN10 | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs1460275142, COSV54375544; called by muse, mutect2, varscan2
- CCDC180 | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1215740852, COSV100827219; called by muse, mutect2, varscan2
- CDC5L | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV101015150; called by muse, mutect2, varscan2
- CEACAM1 | c.29G>C p.R10T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.465); catalogued as COSV50733194; called by mutect2, varscan2
- CENPF | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100871891; called by muse, mutect2, varscan2
- CGB2 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100031736; called by mutect2, varscan2
- CIP2A | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as COSV99843083; called by muse, mutect2, varscan2
- COL11A1 | c.1646C>T p.S549F | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV100617826; called by muse, mutect2, varscan2
- COL5A2 | c.3448C>A p.L1150I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100880663; called by muse, mutect2, varscan2
- CSGALNACT2 | c.974T>C p.V325A | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.248); catalogued as COSV100989839; called by muse, mutect2
- CYP4X1 | c.744G>C p.Q248H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.304); catalogued as COSV100903354; called by muse, mutect2, varscan2
- DCTN1 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100721032, COSV62619893; called by muse, mutect2, varscan2
- DMRT3 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs769032439, COSV51905568; called by mutect2, varscan2
- DNAH11 | c.4884C>G p.F1628L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs762090852, COSV100177389, COSV100180270; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJB11 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV99408706; called by muse, mutect2
- DNAJB13 | c.392G>C p.R131P | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.836); catalogued as COSV100334508, COSV60271303; called by muse, mutect2, varscan2
- DPM1 | c.477G>C p.L159F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as COSV100857746; called by muse, mutect2, varscan2
- EIF4G3 | c.280C>A p.P94T | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.031); catalogued as COSV51691367, COSV99945214; called by muse, mutect2
- EPHB2 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs780057705, COSV101007319; called by muse, mutect2, varscan2
- FAAP100 | c.1615C>T p.Q539* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs987278315, COSV100585534; called by muse, mutect2, varscan2
- FAM83G | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV58756629, COSV58759158; called by muse, mutect2, varscan2
- FBF1 | c.2473C>T p.R825W (on ENST00000586717; = p.R839W on NM_001319193.1) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV59865482; called by muse, mutect2, varscan2
- FCN2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs369954653; called by muse, mutect2, varscan2
- FIG4 | c.821G>C p.R274T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100020110; called by muse, mutect2, varscan2
- FRMD4A | c.2929C>G p.P977A | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.04); catalogued as rs754169439, COSV100662315; called by muse, mutect2, varscan2
- FRY | c.5463G>C p.K1821N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV100968917, COSV100969772; called by muse, mutect2, varscan2
- GALNT13 | c.479-1G>T p.X160_splice | Splice Site (SNP) | VAF 8/72 reads (11%) | catalogued as COSV101224005; called by muse, varscan2
- GARNL3 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100150599; called by muse, mutect2, varscan2
- GFM1 | c.166G>C p.D56H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51833757, COSV99963089; called by muse, mutect2
- GIMAP4 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs753014940, COSV55435476; called by muse, mutect2, varscan2
- GMPR | c.80G>C p.R27P | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99440433; called by muse, mutect2, varscan2
- HACD4 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV101529964; called by muse, mutect2, varscan2
- HLA-E | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.991); catalogued as COSV100931909, COSV100931976, COSV64927856; called by muse, mutect2, varscan2
- HMCN1 | c.15545G>A p.R5182Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs148826584; called by muse, mutect2, varscan2
- HNRNPK | c.723G>T p.M241I | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100699106; called by muse, mutect2
- HOOK2 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV99317794; called by muse, mutect2
- HR | c.2789C>G p.S930* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100455981; called by muse, mutect2, varscan2
- HS6ST3 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.141); catalogued as rs1244714799, COSV100941370; called by muse, mutect2, varscan2
- IGF2BP2 | c.126C>A p.F42L | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100649448; called by muse, varscan2
- IGSF10 | c.3904A>G p.I1302V | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs369750496; called by muse, mutect2, varscan2
- IL18BP | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.043); catalogued as rs370464613; called by muse, mutect2, varscan2
- ITGA6 | c.3128C>G p.S1043* (on ENST00000442250; = p.S1004* on NM_000210.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/90 reads (13%) | catalogued as COSV99905904; called by muse, varscan2
- KHSRP | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101231231; called by muse, mutect2
- KMO | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100844813; called by muse, mutect2, varscan2
- KMT2C | c.9374G>C p.R3125T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100075288; called by muse, mutect2, varscan2
- L3MBTL1 | c.617C>T p.S206F (on ENST00000418998 / NM_001377303.1; = p.S116F on NM_015478.7) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as rs1469687596, COSV100917277; called by muse, mutect2, varscan2
- LCE2C | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV100909466; called by muse, mutect2, varscan2
- LRP2 | c.7664G>C p.G2555A | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as COSV99789799; called by muse, mutect2, varscan2
- MAF | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV100391950; called by muse, mutect2, varscan2
- MAGEA3 | c.228C>G p.N76K | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0.076); catalogued as COSV100939078; called by muse, mutect2, varscan2
- MIA2 | c.2351C>G p.S784* | Nonsense Mutation (SNP) | VAF 15/104 reads (14%) | catalogued as COSV54492144, COSV99698061; called by muse, mutect2, varscan2
- MTO1 | c.1782G>C p.L594F (on ENST00000370300 / NM_133645.3; = p.L569F on NM_012123.4) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.053); catalogued as COSV100940510; called by muse, mutect2, varscan2
- MUC16 | c.22607C>A p.P7536Q | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.529); catalogued as rs373373247; called by muse, mutect2, varscan2
- MYO5B | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.077); catalogued as COSV99546009; called by muse, mutect2, varscan2
- NAF1 | c.614C>G p.S205* | Nonsense Mutation (SNP) | VAF 10/86 reads (12%) | catalogued as COSV99918855; called by muse, mutect2, varscan2
- NAV3 | c.2132+8dup p.X711_splice | Splice Site (INS) | VAF 7/32 reads (22%) | catalogued as rs762130643; called by mutect2, varscan2
- NKPD1 | c.1384G>C p.D462H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100521696; called by muse, mutect2
- NSD1 | c.2784G>A p.M928I | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as rs955800652; called by muse, mutect2
- NSD2 | c.3377G>A p.R1126H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56388763; called by mutect2, varscan2
- OGN | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99364243; called by muse, mutect2, varscan2
- OR5F1 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.611); catalogued as COSV99558849; called by muse, mutect2, varscan2
- OR7A10 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.095); catalogued as rs770049554, COSV99932508; called by muse, mutect2, varscan2
- PAPLN | c.3214C>T p.P1072S (on ENST00000554301; = p.P1045S on NM_173462.4) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.067); catalogued as COSV99390248; called by muse, mutect2, varscan2
- PLCL1 | c.1720G>T p.G574C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as COSV101407249; called by muse, mutect2, varscan2
- PLG | c.89G>C p.G30A | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99805004; called by muse, mutect2
- PLXNB2 | c.2542C>T p.Q848* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as COSV100834237; called by muse, mutect2, varscan2
- PPP1R3A | c.2528C>A p.T843K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.198); catalogued as COSV99493823; called by muse, mutect2, varscan2
- PRRC2B | c.313C>G p.Q105E | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as COSV100622001, COSV100622111; called by muse, mutect2
- RABGAP1L | c.17C>A p.S6* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99273216; called by mutect2, varscan2
- RP1 | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV55116133, COSV55123375; called by muse, mutect2, varscan2
- SEC24A | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV100524647; called by muse, mutect2, varscan2
- SECISBP2L | c.746G>C p.R249T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99960833; called by mutect2, varscan2
- SLC13A1 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52015160; called by muse, mutect2, varscan2
- SLC27A3 | c.2286C>G p.F762L (on ENST00000271857; = p.F634L on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV99670097; called by muse, mutect2, varscan2
- SPEF2 | c.2473G>A p.G825R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV61550383; called by muse, mutect2
- SSBP4 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.314); catalogued as COSV99526269; called by muse, mutect2, varscan2
- SULT1C2 | c.321G>C p.K107N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV52264768, COSV99265364; called by muse, mutect2, varscan2
- TECPR2 | c.3664G>A p.A1222T | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV100850160; called by muse, mutect2, varscan2
- THOC2 | c.3578C>T p.P1193L | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs1248505410, COSV55558929; called by muse, mutect2
- TNNT1 | c.41C>G p.P14R | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.01); catalogued as COSV99402978; called by muse, mutect2
- TOGARAM1 | c.1418G>C p.C473S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100753230; called by muse, mutect2, varscan2
- TRIOBP | c.2113G>A p.D705N | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs761994874, COSV60373517; called by muse, varscan2
- TRIOBP | c.2192G>A p.R731K | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV100731054; called by muse, varscan2
- TTN | c.62848C>G p.L20950V (on ENST00000591111; = p.L13526V on NM_003319.4) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | PolyPhen benign (0.021); catalogued as COSV100611960; called by muse, mutect2, varscan2
- USH2A | c.9533C>G p.S3178C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV100228067, COSV56353278; called by muse, mutect2, varscan2
- VPS37C | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.914); catalogued as COSV100075277; called by muse, mutect2, varscan2
- XKR9 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as rs766718346, COSV101281968; called by muse, mutect2, varscan2
- ZC3HC1 | c.293C>G p.S98C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as COSV100315980; called by mutect2, varscan2
- ZFHX4 | c.9741G>C p.Q3247H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV99266328; called by muse, mutect2, varscan2
- ZNF224 | c.240C>A p.D80E | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0.029); catalogued as COSV100425495; called by muse, mutect2
- ZNF385D | c.115T>C p.F39L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as rs1289689327, COSV99875933; called by muse, mutect2, varscan2
- ZNF557 | c.257C>T p.S86F (on ENST00000414706 / NM_001044388.2; = p.S93F on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as COSV99422688; called by muse, mutect2
- CMKLR1 | c.1012C>G p.L338V (on ENST00000312143 / NM_001142344.2; = p.L336V on NM_004072.3) | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); called by muse, mutect2
- ANAPC1 | c.5163G>A p.Q1721= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV100594998; called by muse, mutect2, varscan2
- CD300C | c.294G>A p.E98= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV100423314, COSV58170705; called by muse, mutect2, varscan2
- CNR1 | c.475C>T p.L159= | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- CRYBG1 | c.3972G>A p.L1324= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV64811600; called by mutect2, varscan2
- DENND1C | c.1149G>T p.L383= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV101200242; called by muse, mutect2, varscan2
- FGL2 | c.336C>T p.N112= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs1324391314, COSV99593002; called by muse, mutect2, varscan2
- GADD45B | c.423C>T p.Y141= | Silent (SNP) | VAF 22/165 reads (13%) | catalogued as COSV99298126; called by muse, mutect2, varscan2
- H2BC13 | c.114C>T p.Y38= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as rs1264097944, COSV100704422; called by muse, mutect2
- HUWE1 | c.8043G>C p.L2681= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV99473763; called by muse, mutect2, varscan2
- ITGAV | c.276T>C p.S92= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99655500; called by muse, mutect2, varscan2
- KIAA1549L | c.3774G>T p.L1258= (on ENST00000321505; = p.L1555= on NM_012194.3) | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99684181; called by muse, mutect2, varscan2
- KIFAP3 | c.27C>G p.L9= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100847098, COSV63040574; called by muse, mutect2, varscan2
- MKNK2 | c.603C>A p.I201= | Silent (SNP) | VAF 13/254 reads (5%) | catalogued as COSV99170382; called by muse, mutect2
- PDCD10 | c.532C>T p.L178= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV101208559; called by muse, mutect2, varscan2
- PDILT | c.351G>A p.K117= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV100199729; called by muse, mutect2, varscan2
- PIM2 | c.882C>T p.P294= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV99900424; called by muse, mutect2, varscan2
- PPM1A | c.894G>A p.S298= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as rs370598236; called by muse, mutect2, varscan2
- PPP4R4 | c.36C>T p.F12= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV58557393; called by muse, mutect2
- PRKD2 | c.807C>T p.I269= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99354552; called by muse, mutect2, varscan2
- RABEP1 | c.1596T>G p.R532= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV99336914; called by muse, mutect2, varscan2
- RGS9 | c.960C>G p.L320= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV99287851; called by muse, mutect2
- RIMS2 | c.2409C>T p.V803= (on ENST00000666250 / NM_001348490.2; = p.V611= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV99187860; called by muse, mutect2, varscan2
- SGTA | c.468G>A p.P156= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs534834001, COSV99682649; called by muse, mutect2, varscan2
- SIPA1L1 | c.1662C>T p.D554= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs759853799, COSV62170207, COSV62173343; called by muse, mutect2, varscan2
- SLC20A2 | c.309G>A p.L103= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100646177; called by muse, mutect2, varscan2
- TAF4 | c.2952G>A p.L984= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99434791; called by muse, mutect2, varscan2
- TBK1 | c.588G>A p.K196= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100538333; called by muse, mutect2, varscan2
- TENM1 | c.1470G>A p.S490= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs979095690, COSV64448814; called by muse, mutect2, varscan2
- TTC9 | c.621G>T p.T207= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99832874; called by muse, mutect2, varscan2
- ZEB2 | c.486C>T p.S162= | Silent (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- AL353804.4 | chrX:73824299 C>G | 5'Flank (SNP) | VAF 4/33 reads (12%) | called by mutect2, varscan2
